CCDI case PBBSIJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/a334659c-dfc8-46cf-b5ee-c1f3b0da6ca2

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Synovial sarcoma, biphasic: ICD-O-3 morphology code: 9043/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 10.7 years (3,904 days).

Biospecimens (3 samples)
- Sample 0DFSQL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFSS5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFSSV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
